Somatic mutation profile of tumor specimen 0DUETT from CCDI case PBCKXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cranial nerve, NOS; Age at diagnosis: 6.1 years (2,226 days).
Specimen 0DUETT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c01c164f-8405-4e8c-9b93-bfbc7daa8080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b404521-c93e-42ea-9185-8c6f2650c5de

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK1 | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 232/673 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99732899; called by muse, mutect2, varscan2
- MLC1 | c.442C>T p.L148= | Silent (SNP) | VAF 95/258 reads (37%) | called by muse, mutect2, varscan2
